Somatic mutation profile of tumor specimen TCGA-2H-A9GR-01A (aliquot TCGA-2H-A9GR-01A-12D-A37C-09) from TCGA case TCGA-2H-A9GR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 80.6 years (29,451 days).
Specimen TCGA-2H-A9GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b947261-52ba-4a3c-a211-de9cc7c54aa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GR-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GR-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db4bab46-27e9-45dc-88f3-704000a740de

The open-access MAF lists 332 somatic variants for this specimen: 252 protein-altering or splice-affecting, 61 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 61, Nonsense Mutation 14, Intron 8, RNA 7, Splice Site 4, Frame Shift Del 4, Splice Region 2, In Frame Del 2, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3169G>A p.V1057M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs537267668, COSV57059874; called by muse, mutect2, varscan2
- ACTR3B | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV55449592; called by muse, mutect2
- AKT2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1206035617, COSV60910521; called by muse, mutect2, varscan2
- AMDHD1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57140072; called by muse, mutect2, varscan2
- ASIC2 | c.1196+1G>A p.X399_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as rs199653464, COSV56754829; called by muse, mutect2, varscan2
- ATP4A | c.2006A>C p.K669T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV52866059; called by muse, mutect2, varscan2
- ATP9B | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751623399, COSV56951847, COSV56958974; called by muse, mutect2, varscan2
- BCHE | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52262346; called by muse, mutect2, varscan2
- BCHE | c.500T>G p.V167G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012379; called by muse, mutect2, varscan2
- C3 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as rs772505177, COSV55573273; called by muse, mutect2, varscan2
- CAMTA1 | c.4693G>A p.A1565T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372219946; called by muse, mutect2, varscan2
- CHRM2 | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57783351; called by muse, mutect2, varscan2
- CLEC4G | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1250842245; called by muse, mutect2
- COL12A1 | c.5894G>A p.R1965H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs199747984, COSV59392343; called by muse, mutect2, varscan2
- COL6A3 | c.4831A>G p.N1611D | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1168164012; called by muse, mutect2, varscan2
- CPXM2 | c.2248C>T p.Q750* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs139450310; called by muse, mutect2, varscan2
- CRMP1 | c.1277A>G p.K426R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61480980; called by muse, mutect2, varscan2
- CRTAC1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs752821214; called by muse, mutect2, varscan2
- CYP2A13 | c.831+1G>A p.X277_splice | Splice Site (SNP) | VAF 11/119 reads (9%) | catalogued as rs780057919; called by muse, mutect2
- DDI1 | c.672A>T p.E224D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV56387352; called by muse, mutect2, varscan2
- DFFB | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747227784, COSV58861974; called by muse, mutect2, varscan2
- DGKI | c.2000T>G p.V667G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750514798; called by muse, mutect2, varscan2
- DISP3 | c.3880G>A p.V1294I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.686); catalogued as rs775248733, COSV53823292; called by muse, mutect2, varscan2
- EPHA3 | c.1568A>G p.K523R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV60719793, COSV60731934; called by mutect2, varscan2
- FGB | c.306G>A p.L102= | Splice Region (SNP) | VAF 7/42 reads (17%) | catalogued as rs1328349321, COSV57417715; called by muse, mutect2, varscan2
- FILIP1 | c.2490A>C p.E830D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV99385480; called by muse, mutect2, varscan2
- FLNC | c.6133C>T p.R2045W | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs762748670; called by muse, mutect2, varscan2
- FLT1 | c.3803C>T p.S1268L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs368266056, COSV56724189; called by muse, mutect2, varscan2
- GALNT17 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61197769; called by muse, mutect2, varscan2
- GALNT17 | c.1660T>G p.F554V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100353835; called by muse, mutect2, varscan2
- GHRHR | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763314210; called by muse, mutect2, varscan2
- HADH | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as rs1416395797; called by muse, mutect2, varscan2
- HSPBP1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.241); catalogued as rs199687590; called by mutect2, varscan2
- HTR1F | c.31T>G p.L11V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100138195, COSV60389317; called by muse, mutect2, varscan2
- IGHG4 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as rs778619198; called by muse, mutect2, varscan2
- IGSF10 | c.5801T>G p.M1934R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV56785424; called by muse, mutect2, varscan2
- IL20 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs369436616; called by muse, mutect2, varscan2
- ITGB6 | c.585C>A p.N195K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1038189073; called by muse, mutect2, varscan2
- KCNMA1 | c.2894A>C p.N965T (on ENST00000286628 / NM_001161352.2; = p.N907T on NM_002247.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as rs577988617; called by mutect2, varscan2
- KCNT2 | c.301A>C p.S101R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1410680251, COSV99654835, COSV99655778; called by muse, mutect2, varscan2
- KIT | c.2089C>G p.H697D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.174); catalogued as COSV55412612, COSV55419237; called by muse, mutect2, varscan2
- KLHL1 | c.1193T>A p.L398H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100917169; called by muse, mutect2, varscan2
- KRT1 | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs1266622092; called by mutect2, varscan2
- LAMA1 | c.5782A>C p.T1928P | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV67542901; called by muse, mutect2, varscan2
- LAMA1 | c.3805G>C p.V1269L | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV67535849; called by muse, mutect2
- LAMA1 | c.1482A>C p.E494D | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV67533923; called by muse, mutect2, varscan2
- LRP1 | c.7831C>T p.R2611C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs377122314, COSV54503458; called by muse, mutect2, varscan2
- LRP1B | c.13304A>G p.K4435R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV101254879, COSV67186665, COSV67220594; called by muse, mutect2, varscan2
- LRP1B | c.6367A>T p.R2123* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV67221808; called by muse, mutect2, varscan2
- LRRC14 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs772545920, COSV52884239; called by muse, mutect2, varscan2
- LRRN3 | c.1890G>T p.M630I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57823510; called by muse, mutect2, varscan2
- MAJIN | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs758734857; called by muse, mutect2, varscan2
- MAP4K4 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1191731616; called by muse, mutect2, varscan2
- MC4R | c.476A>C p.N159T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV55351367; called by muse, mutect2, varscan2
- MELTF | c.1984G>T p.D662Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170687680; called by muse, mutect2, varscan2
- MTSS1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100275610; called by muse, mutect2
- MYO1H | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs369196571; called by muse, mutect2
- NAALAD2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV100428466; called by muse, mutect2
- NALCN | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51922474; called by muse, mutect2, varscan2
- NDN | c.874T>C p.S292P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV59360917; called by muse, mutect2, varscan2
- NEBL | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as rs754463343, COSV65805314; called by muse, mutect2, varscan2
- NETO1 | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as rs765206728, COSV55002144, COSV55003500; called by muse, mutect2, varscan2
- NLGN1 | c.1025T>G p.L342R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64328993; called by muse, mutect2, varscan2
- OLFM3 | c.257T>G p.L86R (on ENST00000338858 / NM_001288821.1; = p.L66R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58796124, COSV58798328; called by muse, mutect2
- OR4C16 | c.910T>G p.L304V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV58943970; called by muse, mutect2, varscan2
- OR51G1 | c.445A>C p.S149R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV58968526, COSV58971231; called by muse, mutect2, varscan2
- OR52A5 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100263259, COSV56614108; called by muse, mutect2, varscan2
- OR7D4 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV100432849; called by muse, mutect2, varscan2
- OTOF | c.5626C>T p.P1876S (on ENST00000272371 / NM_194248.3; = p.P1109S on NM_004802.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs376585613; called by muse, mutect2, varscan2
- OXR1 | c.2552del p.T851Sfs*26 (on ENST00000442977 / NM_001198532.1; = p.T823Sfs*26 on NM_018002.3) | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as COSV52427781; called by mutect2, pindel, varscan2
- PCDH9 | c.3215A>G p.E1072G (on ENST00000377865 / NM_203487.3; = p.E1038G on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100121698, COSV60526615; called by mutect2, varscan2
- PCLO | c.4591A>C p.T1531P | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV61665994; called by muse, mutect2, varscan2
- PHKG1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs767151786, COSV51916388, COSV99304994; called by muse, mutect2, varscan2
- PIK3C2B | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs751633435, COSV100915963; called by muse, mutect2, varscan2
- PLIN4 | c.2627T>C p.V876A (on ENST00000301286; = p.V891A on NM_001367868.2) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as rs1256444204, COSV56687953; called by muse, mutect2, varscan2
- PRSS12 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367921225; called by muse, mutect2, varscan2
- PTGS1 | c.1729G>A p.V577I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.266); catalogued as rs533328230; called by muse, mutect2, varscan2
- PTPN4 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs1246147420, COSV55308478; called by muse, mutect2, varscan2
- RANBP17 | c.3064A>C p.S1022R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV66656069; called by muse, mutect2, varscan2
- RBFA | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs749107520; called by muse, mutect2, varscan2
- RBM27 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54589288; called by muse, mutect2, varscan2
- RFX6 | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100263593; called by muse, mutect2, varscan2
- RSPO4 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs765335066, COSV54083496; called by muse, mutect2, varscan2
- RYR3 | c.10061G>A p.R3354Q (on ENST00000389232; = p.R3355Q on NM_001036.6) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs747213308, COSV101214727; called by muse, mutect2
- SALL3 | c.1589T>G p.L530R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101610110; called by muse, mutect2, varscan2
- SATB2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV99610958; called by muse, mutect2
- SCN9A | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57617191; called by muse, mutect2
- SEMA6D | c.2941T>G p.L981V (on ENST00000316364 / NM_153618.2; = p.L919V on NM_020858.2) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs758330754, COSV60373388, COSV60376846; called by muse, mutect2, varscan2
- SIM1 | c.2244A>C p.Q748H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV53493231; called by muse, mutect2, varscan2
- SLC29A4 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267228610; called by muse, mutect2
- SLC2A12 | c.1747_1749del p.E583del | In Frame Del (DEL) | VAF 33/98 reads (34%) | catalogued as rs751060928; called by pindel, varscan2
- SLC7A3 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as rs1459882610; called by muse, mutect2, varscan2
- SLC8A1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60479849; called by muse, mutect2, varscan2
- SLITRK2 | c.1978T>G p.L660V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV59424494, COSV59427859; called by muse, mutect2, varscan2
- SMARCAD1 | c.2321T>C p.V774A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs112326108; called by mutect2, varscan2
- SNRPN | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV57595204; called by muse, mutect2, varscan2
- SNTG1 | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV52445741, COSV52474615; called by muse, mutect2, varscan2
- SYNE1 | c.21531A>C p.Q7177H (on ENST00000367255 / NM_182961.4; = p.Q7106H on NM_033071.3) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV55020376; called by muse, mutect2, varscan2
- TG | c.4981C>A p.R1661S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55069428; called by muse, mutect2, varscan2
- TG | c.7111C>T p.R2371* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as rs1410846026, COSV55085851; called by muse, mutect2, varscan2
- TNC | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs765997924; called by muse, mutect2, varscan2
- TRHDE | c.939A>C p.E313D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.159); catalogued as rs1330602213, COSV53865427; called by muse, mutect2, varscan2
- TRIM9 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as COSV53613708; called by muse, mutect2
- TSGA10 | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770177431; called by muse, mutect2, varscan2
- TTN | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | PolyPhen benign (0.022); catalogued as rs1370693255, COSV59885027, COSV59992224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC13C | c.5714A>C p.K1905T | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.998); catalogued as rs1282180281; called by muse, mutect2, varscan2
- UPK3B | c.340_341del p.V114Lfs*32 (on ENST00000257632; = p.V59Lfs*32 on NM_001347684.2) | Frame Shift Del (DEL) | VAF 28/180 reads (16%) | catalogued as rs751773773; called by pindel, varscan2
- USP29 | c.1637A>C p.K546T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs187226665, COSV54142095; called by muse, mutect2, varscan2
- VCAN | c.8983A>T p.S2995C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV54104052; called by muse, mutect2, varscan2
- VPS4A | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs759795974; called by muse, mutect2, varscan2
- WDR72 | c.802A>G p.R268G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765198263; called by muse, mutect2, varscan2
- XRCC1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as rs574450911, COSV99486487; called by muse, mutect2, varscan2
- ZNF407 | c.6503C>T p.T2168M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs745331996, COSV55260941; called by muse, mutect2, varscan2
- ZNF496 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs148779406; called by muse, mutect2, varscan2
- ZNF667 | c.1659A>C p.K553N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV99410221; called by muse, mutect2, varscan2
- ZNF831 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs1209000145; called by mutect2, varscan2
- ZNF98 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100757567, COSV63334161; called by muse, mutect2, varscan2
- ABCD2 | c.1584G>A p.W528* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.1064T>C p.L355P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.2037A>C p.E679D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRL2 | c.1435T>C p.W479R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- AKNAD1 | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALMS1 | c.12492A>C p.K4164N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF35 | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by mutect2, varscan2
- ARID1A | c.4036C>T p.Q1346* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- BBS9 | c.977T>G p.L326R | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BICC1 | c.2227T>G p.L743V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- BNC2 | c.2549T>G p.L850R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C9orf85 | c.286T>C p.C96R | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA2D3 | c.2251T>G p.F751V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CAMKK2 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC85A | c.865A>G p.S289G | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCSER1 | c.1465A>G p.R489G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CFAP58 | c.2444T>C p.L815P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHAC1 | c.636C>G p.F212L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- CHSY3 | c.2002A>G p.S668G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLEC7A | c.104-2A>T p.X35_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- CNTN1 | c.853del p.T285Lfs*18 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- CNTN6 | c.998A>T p.D333V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP4 | c.1312T>G p.L438V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CXCL14 | c.263A>G p.K88R (on ENST00000337225; = p.K76R on NM_004887.5) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- CYLC2 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CYP4F2 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DLX5 | c.15T>G p.F5L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DMXL2 | c.3608_3655del p.E1203_L1218del | In Frame Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel
- DOCK3 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK4 | c.113A>C p.K38T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ELMO1 | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- EPHB6 | c.2491C>A p.P831T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERO1B | c.746T>G p.L249R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAHD1 | c.12G>T p.M4I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- FASTKD5 | c.804T>A p.Y268* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- FBN1 | c.2811T>A p.C937* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- FMN2 | c.4199A>G p.Q1400R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- FOLH1 | c.1272A>C p.E424D | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBE1 | c.1651T>G p.F551V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBF1 | c.2501T>C p.L834P (on ENST00000369983 / NM_001377137.1; = p.L833P on NM_004193.3) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GMIP | c.1854C>G p.D618E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GML | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRIN2A | c.3233A>C p.K1078T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- GZMA | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HAS1 | c.1030A>G p.N344D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- HEPHL1 | c.3296A>G p.Q1099R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- HMGN5 | c.159A>C p.E53D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- HOMER1 | c.218A>C p.K73T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ICE1 | c.5314A>G p.N1772D | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IDO2 | c.316G>A p.V106I (on ENST00000389060; = p.V119I on NM_194294.2) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IKZF5 | c.273C>A p.S91R | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IL12RB2 | c.554T>A p.I185N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- IVL | c.1317A>C p.Q439H | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JAKMIP2 | c.1281+2T>C p.X427_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- KCNQ4 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD19 | c.1346T>C p.L449P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL32 | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- L3MBTL4 | c.989T>G p.F330C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMB4 | c.3385G>T p.D1129Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LMBRD1 | c.954A>C p.K318N (on ENST00000649011; = p.K296N on NM_018368.4) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRGUK | c.1675G>T p.V559F | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- LRP1B | c.13137T>G p.F4379L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.1414A>C p.S472R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- LRRC18 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LRRC6 | c.1308A>C p.K436N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- LRRIQ1 | c.2505C>A p.S835R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- LRRK2 | c.2231T>C p.L744S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYPD5 | c.380C>T p.P127L (on ENST00000377950 / NM_001031749.3; = p.P84L on NM_182573.2) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAEL | c.728T>G p.L243R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MAFB | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- MARK1 | c.280A>C p.T94P | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MDGA2 | c.2317T>G p.L773V (on ENST00000399232 / NM_001113498.2; = p.L475V on NM_182830.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEIS1 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- MMRN1 | c.2602A>C p.K868Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- MORC2 | c.2201C>T p.P734L (on ENST00000397641 / NM_001303256.3; = p.P672L on NM_014941.3) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MRC1 | c.3584T>C p.L1195P | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTOR | c.7012G>A p.D2338N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1L | c.566A>C p.N189T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- NELL1 | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEXMIF | c.439T>G p.L147V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OPN3 | c.838A>G p.N280D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- OR10J5 | c.257T>G p.I86S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- OR13D1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR56A1 | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR5D14 | c.467T>G p.F156C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PAPPA2 | c.1378T>G p.F460V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PCLO | c.8377G>T p.E2793* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- PDYN | c.631T>G p.L211V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- PIKFYVE | c.2779A>G p.S927G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEC | c.10214A>G p.Q3405R (on ENST00000322810 / NM_201380.4; = p.Q3295R on NM_000445.5) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA4 | c.1224C>A p.D408E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- POSTN | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPP2R1A | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF5 | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.381); called by mutect2, varscan2
- PRKN | c.269A>C p.N90T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTGDS | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- PTP4A1 | c.381A>C p.E127D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PTPA | c.742G>A p.D248N (on ENST00000337738 / NM_178001.2; = p.D213N on NM_021131.5) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PTPRT | c.1991T>G p.F664C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, varscan2
- PTPRT | c.1939T>C p.S647P | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- RAB11B | c.314G>A p.W105* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- RAB21 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- RALGAPA2 | c.5123C>T p.P1708L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REC8 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMS1 | c.4769A>G p.K1590R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RIMS2 | c.4570T>C p.W1524R (on ENST00000666250 / NM_001348490.2; = p.W1095R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RLN3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ROBO2 | c.2291C>G p.P764R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- RPS11 | c.355_371del p.D119Hfs*47 | Frame Shift Del (DEL) | VAF 3/40 reads (8%) | called by mutect2, pindel
- RTCB | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RTEL1 | c.3253G>T p.A1085S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SAMSN1 | c.758T>G p.I253S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SEMA5A | c.1133A>C p.K378T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SIRT6 | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SLCO1B3 | c.253A>C p.S85R | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO6A1 | c.450T>G p.S150R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SPATA31A1 | c.3078A>C p.Q1026H | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPRED2 | c.1053T>A p.Y351* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- STAMBP | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- STEAP2 | c.1178T>C p.F393S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SULF1 | c.883A>C p.R295= | Splice Region (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- TBP | c.537C>A p.D179E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TINAG | c.929T>C p.F310S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TMEM26 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM61 | c.11T>A p.V4D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- TRPA1 | c.1807A>G p.K603E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSPOAP1 | c.2033T>G p.L678R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC17 | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TTN | c.35636T>G p.V11879G (on ENST00000591111; = p.V4455G on NM_003319.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TYR | c.1012T>G p.F338V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.575); called by muse, mutect2
- UBASH3B | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- UBE3A | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ZNF429 | c.808T>G p.S270A | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF441 | c.882C>G p.S294R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ACKR1 | c.978T>G p.S326= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.3552G>A p.V1184= (on ENST00000398564; = p.V1159= on NM_014629.4) | Silent (SNP) | VAF 13/203 reads (6%) | catalogued as rs1303752689; called by muse, mutect2
- ASXL3 | c.4140A>G p.E1380= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ATAD2 | c.2637A>G p.T879= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- C2CD2 | c.1089G>A p.T363= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1342030769, COSV61599078; called by mutect2, varscan2
- CDH11 | c.597C>T p.Y199= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- CFHR5 | c.867T>C p.H289= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- CHRNG | c.1446G>A p.S482= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs375174291; called by muse, mutect2, varscan2
- CNR1 | c.72C>T p.G24= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs941629903; called by muse, mutect2
- CSMD2 | c.7488C>T p.N2496= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs765627105, COSV53966778; called by muse, mutect2, varscan2
- CYP26B1 | c.1503G>A p.L501= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1489140636; called by muse, mutect2, varscan2
- DHRS2 | c.339C>T p.G113= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1393894434, COSV51631007; called by muse, varscan2
- FAT3 | c.8505A>G p.Q2835= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99969150; called by muse, mutect2, varscan2
- FBXL13 | c.603C>A p.S201= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57542539; called by muse, mutect2, varscan2
- FCRL3 | c.771T>C p.S257= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100942823, COSV63842650; called by muse, mutect2, varscan2
- GALNT15 | c.576A>C p.T192= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- GMEB1 | c.282T>G p.A94= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- HOGA1 | c.108G>A p.A36= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs747795341, COSV100080820; called by muse, mutect2, varscan2
- HS3ST1 | c.228G>A p.L76= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- KCTD16 | c.981G>A p.T327= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs774023034, COSV101568748; called by muse, mutect2, varscan2
- LACRT | c.183G>A p.Q61= | Silent (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- LPA | c.5430A>G p.Q1810= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as rs770263408, COSV60300733, COSV60312925; called by muse, mutect2, varscan2
- LY75 | c.4986T>A p.P1662= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- MAGEB16 | c.498T>C p.F166= | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- MAP3K7 | c.1317C>T p.S439= (on ENST00000369329 / NM_145331.3; = p.S412= on NM_003188.4) | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100997616; called by muse, mutect2
- MCHR2 | c.576C>T p.D192= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs201955415, COSV56001330; called by muse, mutect2, varscan2
- MNX1 | c.18T>C p.N6= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99429737; called by muse, mutect2, varscan2
- MUC16 | c.19176T>C p.T6392= | Silent (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- NALCN | c.2310A>C p.G770= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV51939813; called by muse, mutect2, varscan2
- NETO1 | c.228A>C p.P76= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.11529G>C p.G3843= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- OPCML | c.987T>A p.A329= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59409651, COSV59428469; called by muse, mutect2, varscan2
- OR1J2 | c.51C>T p.L17= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100093409; called by muse, mutect2, varscan2
- OR2T12 | c.942T>C p.N314= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100527474; called by muse, mutect2, varscan2
- OR4C12 | c.312T>A p.I104= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- OR52K1 | c.822C>A p.V274= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- OR5L1 | c.435T>G p.A145= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV61732719, COSV61734643; called by muse, mutect2, varscan2
- OR6C6 | c.822G>A p.L274= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs769050504, COSV64455732; called by muse, mutect2, varscan2
- PCDHB6 | c.99C>T p.S33= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99170000; called by muse, mutect2, varscan2
- PEG3 | c.4236A>G p.E1412= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55625532, COSV55636235; called by muse, mutect2, varscan2
- PEG3 | c.2034T>G p.T678= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV55642079, COSV99690435; called by muse, mutect2, varscan2
- PLOD1 | c.213G>A p.S71= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs769238622; called by muse, mutect2, varscan2
- PRAMEF2 | c.45G>A p.Q15= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- PSMD6 | c.432C>T p.L144= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- PTPN13 | c.5235T>G p.A1745= (on ENST00000411767 / NM_080683.3; = p.A1726= on NM_006264.3) | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- RIC8A | c.999C>T p.P333= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs372523925; called by muse, varscan2
- ROBO1 | c.3273C>T p.S1091= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs1395537600; called by muse, mutect2, varscan2
- RYR2 | c.1035A>G p.E345= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV63702668; called by muse, mutect2, varscan2
- RYR3 | c.2748G>A p.K916= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- SOX11 | c.1141C>T p.L381= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- SPEF2 | c.4932A>G p.G1644= | Silent (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- STAB2 | c.3861C>T p.C1287= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- TCEAL2 | c.663T>G p.T221= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV61197169; called by muse, mutect2, varscan2
- TG | c.5565T>C p.L1855= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- TNRC18 | c.3384C>T p.P1128= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs541066805; called by muse, mutect2, varscan2
- TNS1 | c.2565A>G p.S855= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- TRIP12 | c.3030A>G p.P1010= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1367935233; called by muse, mutect2, varscan2
- UGT1A5 | c.420C>T p.H140= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- WDR62 | c.2916C>T p.G972= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs781264395; called by muse, mutect2, varscan2
- ZNF492 | c.1573A>C p.R525= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- ZPBP | c.216G>A p.A72= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs144577669; called by muse, mutect2, varscan2
- AGAP7P | n.320C>G | RNA (SNP) | VAF 32/369 reads (9%) | called by muse, mutect2, varscan2
- AGAP7P | n.1511G>T | RNA (SNP) | VAF 20/222 reads (9%) | catalogued as rs1554941383; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820803 G>C | 3'Flank (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- AL590867.2 | n.347A>G | RNA (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- CA10 | c.61+22842A>G | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- CCND3 | c.199-368G>C | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.1834T>G | RNA (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100253673, COSV59721813; called by muse, mutect2, varscan2
- ELAVL4 | chr1:50106376 A>C | 5'Flank (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100836570, COSV100836662; called by muse, mutect2, varscan2
- KCNIP4 | c.62-421142T>G | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as COSV66172673; called by muse, mutect2, varscan2
- MIR513C | n.20A>C | RNA (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- NACA | c.70+4605G>A | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs766001440; called by muse, mutect2, varscan2
- NFASC | c.2471-1505T>G | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- NXF5 | n.1179A>G | RNA (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-47949T>G | Intron (SNP) | VAF 24/108 reads (22%) | catalogued as COSV67440776, COSV67448586; called by muse, mutect2, varscan2
- SNORD115-7 | n.80C>T | RNA (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- TTN | c.34265-4883A>G | Intron (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.10360+3751A>G | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- XIRP2 | c.*1044C>G | 3'UTR (SNP) | VAF 5/39 reads (13%) | catalogued as rs779002530, COSV54697711; called by muse, mutect2
- ZFHX3 | c.-873G>T | 5'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
